Gene-level copy-number profile of tumor specimen ALCH-B2SX-TTP1-A from ALCHEMIST case ALCH-B2SX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,908 days).
Specimen ALCH-B2SX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 90afe601-d7cf-4825-b51c-83b9deb1c891.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/e4064ee2-3490-4671-8875-714a34561757

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 4,931; copy number 2: 53,900; copy number 3: 11; copy number 4: 9; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,857,270–232,878,708, 1 gene (within-gene range 0–2): SNORC.
- chr10:133,246,478–133,247,891, 2 genes: MIR202HG, MIR202.
- chr10:133,362,485–133,373,354, 2 genes: ECHS1, MIR3944.
- chr15:25,199,448–25,250,940, 29 genes (within-gene range 0–2): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:89,906,157–89,938,761, 5 genes (within-gene range 0–1): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:78,168,581–78,173,527, 1 gene: SYNGR2.
- chr18:37,243,776–37,306,333, 3 genes (within-gene range 0–2): AC015961.2, AC090386.1, AC090386.2.
- chr20:3,239,705–3,245,382, 1 gene: AL109976.1.
- chr20:31,605,283–31,645,006, 3 genes: ID1, MIR3193, COX4I2.
- chr20:32,449,755–32,453,607, 1 gene (within-gene range 0–2): AL034550.1.
- chr20:64,034,344–64,039,962, 1 gene (within-gene range 0–1): C20orf204.
- chr22:17,734,138–17,774,770, 2 genes (within-gene range 0–2): BID, MIR3198-1.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,341,859, 1 gene, copy number 5: CR383658.1.

Autosomal genes at a single copy (total copy number 1): 2,075. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
